Somatic mutation profile of tumor specimen MP2PRT-PAUTCU-TMP1-A (aliquot MP2PRT-PAUTCU-TMP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUTCU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 7.2 years (2,645 days).
Specimen MP2PRT-PAUTCU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80d7ce38-f45a-4229-bde3-d83f8ddedfe9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUTCU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUTCU-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cac044ab-17db-461b-9ba8-96e7a72fe431

The open-access MAF lists 25 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 7, Nonsense Mutation 2, In Frame Del 1, 5'Flank 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 56/359 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 172/350 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- RYR1 | c.6838G>A p.V2280I | Missense Mutation (SNP) | VAF 105/268 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as rs193922797, CM023976; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADGRG6 | c.2677C>T p.R893* | Nonsense Mutation (SNP) | VAF 74/242 reads (31%) | catalogued as rs749312742, COSV51594514; called by muse, mutect2, varscan2
- EHMT1 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 56/596 reads (9%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs781024598, COSV100603933; called by muse, mutect2
- FNTA | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 93/260 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV56489817; called by muse, mutect2, varscan2
- HS6ST2 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 141/576 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs776514830, COSV63713062; called by muse, mutect2, varscan2
- KCNB2 | c.1997C>T p.T666M | Missense Mutation (SNP) | VAF 169/422 reads (40%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.306); catalogued as rs758297898, COSV73050312; called by muse, varscan2
- LRP1B | c.7657C>T p.R2553* | Nonsense Mutation (SNP) | VAF 64/250 reads (26%) | catalogued as rs140801406, COSV67186652; called by muse, mutect2, varscan2
- NRSN1 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 46/626 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as rs143725119; called by muse, mutect2
- PPEF1 | c.1643G>A p.R548H | Missense Mutation (SNP) | VAF 43/257 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs72616070, COSV62996287; called by muse, mutect2, varscan2
- CREBBP | c.5867_5873delinsCTG p.V1956Afs*19 | Frame Shift Del (DEL) | VAF 172/466 reads (37%) | called by pindel, varscan2*
- DST | c.3921G>T p.Q1307H (on ENST00000361203 / NM_001374722.1; = p.Q981H on NM_001723.6) | Missense Mutation (SNP) | VAF 70/326 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- MUC16 | c.29516C>A p.T9839N | Missense Mutation (SNP) | VAF 112/317 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- UBAP2L | c.1364_1366del p.P455del | In Frame Del (DEL) | VAF 43/383 reads (11%) | called by pindel, varscan2
- ZNF614 | c.539C>A p.S180Y | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- CFAP46 | c.5613G>A p.A1871= | Silent (SNP) | VAF 153/416 reads (37%) | catalogued as rs779626189, COSV54154502; called by muse, mutect2, varscan2
- FLG | c.2922T>C p.A974= | Silent (SNP) | VAF 214/696 reads (31%) | catalogued as rs368643051; called by muse, mutect2, varscan2
- PCDHGA3 | c.789G>A p.T263= | Silent (SNP) | VAF 113/292 reads (39%) | catalogued as rs752360843, COSV53927617; called by muse, mutect2, varscan2
- QKI | c.939G>A p.A313= | Silent (SNP) | VAF 79/266 reads (30%) | catalogued as rs765276688, COSV51701071, COSV99275639; called by muse, mutect2, varscan2
- SDR42E1 | c.1125C>T p.F375= | Silent (SNP) | VAF 118/365 reads (32%) | catalogued as rs916823490; called by muse, mutect2, varscan2
- TDRD9 | c.2832C>T p.H944= | Silent (SNP) | VAF 60/742 reads (8%) | catalogued as rs1382931400; called by muse, mutect2
- TRIM9 | c.1371C>T p.S457= | Silent (SNP) | VAF 148/560 reads (26%) | catalogued as rs544784389, COSV53615935; called by muse, varscan2
- AGAP1 | c.164-38671G>A | Intron (SNP) | VAF 94/438 reads (21%) | called by muse, mutect2, varscan2
- RGS4 | chr1:163068959 C>T | 5'Flank (SNP) | VAF 66/199 reads (33%) | called by muse, varscan2
